TCGA case TCGA-JY-A6FA — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus; Tissue source site: University Health Network. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3633aeab-a763-438f-ad03-1b4ac8b3a621

Demographics
Sex at birth: male; Race: asian; Country of residence at enrollment: Canada; Age at index: 51 years; Vital status: Dead; Days to death: 1,361 days (3.7 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 52.0 years (18,978 days); Year of diagnosis: 2006; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Cancer detection method: Symptomatic; Esophageal columnar dysplasia degree: High Grade Dysplasia; Esophageal columnar metaplasia present: Yes; Goblet cells columnar mucosa present: No; Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Negative; Lymph nodes positive: 4; Lymph nodes tested: 19.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Epirubicin; Days to treatment start: 152 days; Days to treatment end: 271 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 152 days; Days to treatment end: 271 days; Treatment outcome: Partial Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 53.3 years (19,455 days); Days to diagnosis: 477 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (2 entries)
- Day 477 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 477 days (1.3 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 1,361 days (3.7 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 174 cm; BMI: 21.1.
- Timepoint category: Prior to Diagnosis; Comorbidities: GERD; Reflux treatment type: Medically Treated; Risk factors: GERD.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 14; Alcohol days per week: 7.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 35; Tobacco smoking quit year: 2006; Age at onset: 16.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-JY-A6FA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 80 mg.
  Slide TCGA-JY-A6FA-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-JY-A6FA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-JY-A6FA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: Ontario; Cancer procurement city: Toronto; History neoadjuvant treatment: No; Tumor status: With tumor; Tobacco smoking history indicator: 4; Alcohol consumption frequency: 7; History reflux disease indicator: Yes; History hpylori infection indicator: Never; History barretts esophageal indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Squamous Cell Carcinoma; Method initial path diagnosis: Endoscopic Biopsy; Lymph node sprd radiograph evidence: No; Lymph nodes examined: Yes.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.
- Drug treatment 3: Pharmaceutical therapy drug name: 5 FU.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,361 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,361 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 477 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-JY-A6FA-01A-11D-A33D-01): tumor purity 0.78, ploidy 2.08, whole-genome doublings 0.
